Gene-level copy-number profile of tumor specimen BLGSP-71-06-00142-01B from CGCI case BLGSP-71-06-00142, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00142-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4c8bcdc8-ea14-4cfe-939b-3417a80b7abf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00142-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,760 have no estimate.
https://portal.gdc.cancer.gov/files/4cc90d78-94d8-441f-ac70-e53d631fe03b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 3,265; copy number 2: 51,427; copy number 3: 3,984; copy number 4: 144; copy number 5: 8; copy number 6: 8; copy number 7: 4; copy number 8: 2; copy number 9: 1; copy number 10: 2; copy number 15: 1; copy number 18: 1; copy number 20: 1; copy number 29: 1; copy number 46: 3.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,040,224–89,078,784, 3 genes (within-gene range 0–1): IGKV1-12, IGKV1-13, IGKV2-14.
- chr2:89,128,724–89,135,257, 2 genes (within-gene range 0–1): IGKV2-18, IGKV2-19.
- chr2:89,170,775–89,177,160, 3 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24.
- chr2:89,213,423–89,213,928, 1 gene (within-gene range 0–1): IGKV1-27.
- chr5:71,102,898–71,133,287, 2 genes: NAIPP4, CDH12P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,049,638–70,078,522, 2 genes, copy number 10: SMN2, AC140134.1.
- chr5:70,415,352–70,555,266, 5 genes, copy number 5–20: GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15.
- chr5:70,860,285–70,953,942, 4 genes, copy number 15–46: CDH12P1, SERF1A, SMN1, AC139834.1.
- chr5:71,032,670–71,093,193, 2 genes, copy number 6: GTF2H2, OCLNP1.
- chr7:102,681,836–102,690,469, 1 gene, copy number 18: RASA4DP.
- chr9:65,189,995–65,230,861, 3 genes, copy number 5: BMS1P12, AL512605.1, AL512605.2.
- chr12:123,441,517–123,473,154, 2 genes, copy number 5 (within-gene range 3–5): COPS5P2, SNRNP35.
- chr14:34,541,044–34,546,877, 3 genes, copy number 6: AL445363.3, AL445363.1, RNU1-27P.
- chr15:21,927,657–21,981,245, 3 genes, copy number 7–8: NF1P2, MIR5701-3, OR11J6P.
- chr15:43,599,563–43,618,800, 1 gene, copy number 7 (within-gene range 2–7): STRC.
- chr15:43,614,208–43,632,283, 1 gene, copy number 7 (within-gene range 3–7): AC011330.3.
- chr16:28,700,294–28,701,540, 1 gene, copy number 29: CDC37P1.
- chr16:28,773,824–28,777,534, 1 gene, copy number 9: AC145285.7.
- chr17:59,859,479–59,892,945, 2 genes, copy number 5: TUBD1, NDUFB8P2.
- chr21:44,133,610–44,210,114, 1 gene, copy number 8 (within-gene range 1–8): GATD3A.

Autosomal genes at a single copy (total copy number 1): 409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
